Gene-level copy-number profile of tumor specimen C3L-05175-03 from CPTAC case C3L-05175, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 62.9 years (22,975 days).
Specimen C3L-05175-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 9932636e-5617-493d-acb6-880e637a077f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-05175-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,238 have no estimate.
https://portal.gdc.cancer.gov/files/4be416c8-26f9-4a16-9ee4-0d49b1bf053d

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 21; copy number 1: 589; copy number 2: 11,212; copy number 3: 7,634; copy number 4: 36,928; copy number 5: 1,148; copy number 6: 709; copy number 7: 75; copy number 8: 1; copy number 11: 33; copy number 12: 8; copy number 24: 7; copy number 25: 1; copy number 35: 6; copy number 39: 2; copy number 55: 11.

Homozygous deletions (total copy number 0; autosomes only): 21 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:11,529,488–11,529,755, 1 gene (within-gene range 0–2): AC022001.1.
- chr10:14,061–254,637, 7 genes: AC215217.1, AL713922.1, TUBB8, IL9RP2, ZMYND11, AL713922.2, RNA5SP297.
- chr10:282,015–441,170, 3 genes (within-gene range 0–2): RNA5SP298, RN7SL754P, AL669841.1.
- chr11:18,933,813–18,939,721, 2 genes: MRGPRX1, AC023078.1.
- chr11:80,527,960–80,528,066, 1 gene: RNU6-544P.
- chr11:80,751,200–80,762,826, 1 gene: LINC02720.
- chr14:106,421,711–106,422,218, 1 gene (within-gene range 0–2): IGHV4-39.
- chr14:106,436,415–106,461,055, 4 genes (within-gene range 0–2): AC244452.1, IGHVII-40-1, IGHV3-41, HOMER2P1.
- chr14:106,470,264–106,470,800, 1 gene (within-gene range 0–2): IGHV3-43.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 68 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:61,561,569–64,511,857, 41 genes, copy number 11–12: PTPRG, Y_RNA, RPL10AP6, RNU2-10P, ID2B, PTPRG-AS1, C3orf14, FEZF2, CADPS, AC012519.1, RN7SL863P, RNU6-139P, AC096915.1, LINC00698, KRT8P35, UBL5P3, SYNPR, SYNPR-AS1, RNA5SP134, SNTN, AC104162.1, C3orf49, THOC7, THOC7-AS1, ATXN7, SCAANT1, PSMD6-AS2, AC012557.1, PSMD6, PSMD6-AS1, AC012557.2, PRICKLE2-AS1, U3, LINC00994, PRICKLE2, PRICKLE2-AS1, PRICKLE2-AS2, PRDX3P4, PRICKLE2-AS3, PRICKLE2-DT, RNU6-739P.
- chr3:68,731,766–70,518,064, 20 genes, copy number 24–55: TAFA4, RNA5SP135, EOGT, AC109587.1, TMF1, MIR3136, UBA3, ARL6IP5, LMOD3, FRMD4B, RBM43P1, AC099328.1, AC099328.2, AC104445.1, MITF, RN7SL418P, SAMMSON, AC139700.1, UQCRHP4, MDFIC2.
- chr3:77,811,741–78,525,485, 7 genes, copy number 25–35: RNU6-217P, LINC02077, AC117462.1, RN7SL647P, RN7SKP61, AC108752.1, MRPS17P3.

Autosomal genes at a single copy (total copy number 1): 589. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
